Gene-level copy-number profile of tumor specimen ALCH-AFFF-TTP1-A from ALCHEMIST case ALCH-AFFF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,172 days).
Specimen ALCH-AFFF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06c2ea33-e514-43b7-b68e-c03eed5e3fe5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFFF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/677a5d1e-0f57-4cfa-9bda-b33962fe090b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 2,498; copy number 2: 50,940; copy number 3: 4,902; copy number 4: 6; copy number 5: 1; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,216,909–1,235,041, 2 genes: SDF4, B3GALT6.
- chr5:93,583,222–93,594,611, 1 gene (within-gene range 0–2): NR2F1.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr15:25,178,738–25,250,940, 40 genes (within-gene range 0–2): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:67,819,704–67,834,582, 1 gene (within-gene range 0–2): SKOR1.
- chr16:67,170,154–67,175,735, 1 gene (within-gene range 0–1): NOL3.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.
- chr22:46,006,616–46,015,498, 2 genes: BX537318.2, BX537318.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:7,383,227–7,450,544, 1 gene, copy number 5: AC013460.1.
- chr19:54,351,384–54,370,558, 1 gene, copy number 7: LAIR1.

Autosomal genes at a single copy (total copy number 1): 2,498. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
